Somatic mutation profile of tumor specimen TCGA-EM-A4FQ-01A (aliquot TCGA-EM-A4FQ-01A-11D-A257-08) from TCGA case TCGA-EM-A4FQ, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, follicular variant; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 42.5 years (15,534 days).
Specimen TCGA-EM-A4FQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 93137785-d714-4456-b93d-fd0d2073c046.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EM-A4FQ-10A (Blood Derived Normal), aliquot TCGA-EM-A4FQ-10A-01D-A25A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/47dd91cd-7c96-4098-bfaa-f6b2608f3381

The open-access MAF lists 7 somatic variants for this specimen: 7 protein-altering or splice-affecting.
By variant classification: Missense Mutation 6, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- NUP93 | c.43C>T p.Q15* | Nonsense Mutation (SNP) | VAF 20/64 reads (31%) | hotspot (GDC flag); catalogued as COSV57428872, COSV57434100; called by muse, mutect2, varscan2
- C16orf46 | c.829G>A p.D277N | Missense Mutation (SNP) | VAF 53/158 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as rs370784988; called by muse, mutect2, varscan2
- COL8A2 | c.800G>A p.G267E | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57442166, COSV57443265; called by muse, mutect2, varscan2
- CTBS | c.947A>G p.Y316C | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.259); catalogued as rs779414200, COSV55364536; called by muse, mutect2, varscan2
- TGFBR2 | c.665A>G p.D222G | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.091); catalogued as COSV55458696; called by muse, mutect2, varscan2
- TRPC7 | c.851C>G p.T284R | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV61462941; called by muse, mutect2, varscan2
